Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4300, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4300-01A (Primary Tumor).

■
Diagnosis/diagnoses:

Total gastrectomy preparation with inclusion of an ulcerated moderately differentiated adenocarcinoma with a maximum diameter of 7 cm with infiltration of the perigastric fatty tissue and circumscribed penetration of the overlying serosa and with a total of fourteen regional lymph node metastases. Tumor-free oral and aboral resection margin. Tumor-free omentum.

Tumor stage: pT3 pN2 (14/35) pMX; ■

Source: NCI Genomic Data Commons file 1429f2fe-7f52-4b63-99aa-05abad2bdb45 (TCGA-CG-4300.0CC3AFAD-BAC0-48D4-85D5-94501AC37A28.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).